Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4201, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4201-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Not specified. Tumor configuration: Not specified. Tumor size: 3 x 2.5 x 1 cm. Histologic type: Adenocarcinoma. Histologic grade: Well differentiated. Extent of invasion: Muscularis propria. Lymph nodes: Not specified. Margins — Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file ee887cec-a392-4efb-b65c-3b9d48eff891 (TCGA-BR-4201.BBB85E42-0484-411A-B564-E83F18734712.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).